Somatic mutation profile of tumor specimen MP2PRT-PASPMM-TMP1-A (aliquot MP2PRT-PASPMM-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASPMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,376 days).
Specimen MP2PRT-PASPMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5668529e-46e4-43c7-8e7b-519977fc487a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPMM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPMM-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4780239-d630-4a6e-980a-08b2b9c0b954

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC166 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 342/862 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as rs781973477; called by muse, varscan2
- CPT1C | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 272/618 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs969419847, COSV54917688; called by muse, varscan2
- TEX15 | c.1949C>T p.T650M (on ENST00000256246; = p.T1033M on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754239055, COSV56348238; called by muse, mutect2, varscan2
- UNC80 | c.5444G>A p.R1815H | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs761112873, COSV55887142; called by muse, mutect2, varscan2
- ANKS1B | c.3037C>T p.R1013* | Nonsense Mutation (SNP) | VAF 69/177 reads (39%) | called by muse, mutect2, varscan2
- CR1L | c.909_919dup p.N307Rfs*45 | Frame Shift Ins (INS) | VAF 144/387 reads (37%) | called by mutect2, varscan2
- DKC1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 161/391 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- IGKV3D-11 | c.345_346del p.H116Hfs*? | Frame Shift Del (DEL) | VAF 84/148 reads (57%) | called by mutect2, pindel, varscan2
- IMPA1 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- RTF1 | c.621_622insTTTCCA p.E207_L208insFP | In Frame Ins (INS) | VAF 92/258 reads (36%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.422_423dup p.A142* | Frame Shift Ins (INS) | VAF 93/282 reads (33%) | called by mutect2, pindel, varscan2
- ZNF490 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DELE1 | c.237G>A p.P79= | Silent (SNP) | VAF 121/320 reads (38%) | catalogued as rs1170169957; called by muse, mutect2, varscan2
- LAMP1 | c.1179G>A p.A393= | Silent (SNP) | VAF 266/638 reads (42%) | catalogued as rs763738666; called by muse, mutect2, varscan2
- TMPRSS9 | c.927G>A p.V309= (on ENST00000648592; = p.V275= on NM_182973.2) | Silent (SNP) | VAF 346/879 reads (39%) | catalogued as rs766048751; called by muse, mutect2, varscan2
